Somatic mutation profile of tumor specimen 0DSL0D from CCDI case PBCHVW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Retinoblastoma, NOS; Tissue or organ of origin: Retina; Age at diagnosis: 2.9 years (1,074 days).
Specimen 0DSL0D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30ea9271-7d22-47ac-9769-69820526d633.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSKZH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/683b8091-7621-4500-bd96-0675e95c81d8

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Nonsense Mutation 1, 5'Flank 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 46/1193 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- KCNQ5 | c.1453A>T p.K485* | Nonsense Mutation (SNP) | VAF 50/1140 reads (4%) | called by muse, mutect2
- CASZ1 | c.933G>A p.K311= | Silent (SNP) | VAF 155/450 reads (34%) | catalogued as rs761557328; called by muse, mutect2, varscan2
- TNXB | c.8769G>A p.G2923= (on ENST00000647633; = p.G2676= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 91/504 reads (18%) | called by muse, mutect2, varscan2
- PARP2 | chr14:20343434 del A | 5'Flank (DEL) | VAF 80/304 reads (26%) | called by mutect2, varscan2
